Somatic mutation profile of tumor specimen TCGA-WB-A816-01A (aliquot TCGA-WB-A816-01A-11D-A35I-08) from TCGA case TCGA-WB-A816, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 42.2 years (15,400 days).
Specimen TCGA-WB-A816-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c5cb9bf-97ea-4ff8-9c87-ee764e85f057.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A816-10A (Blood Derived Normal), aliquot TCGA-WB-A816-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9de371a-75ff-42e4-8b18-599c3ec9f68b

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRX6 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV51859108; called by muse, mutect2, varscan2
- COG7 | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CTDSP2 | c.656C>G p.S219W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SHISA4 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2
- SLC9A8 | c.1006C>A p.H336N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SORBS1 | c.1599G>T p.K533N (on ENST00000361941 / NM_001034954.2; = p.K323N on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- TRAK2 | c.161A>T p.Y54F | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF182 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.113); called by muse, mutect2
- COG7 | c.396C>T p.S132= | Silent (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
